Surgical pathology report (de-identified scan), TCGA case TCGA-35-5375, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Cureline, specimen TCGA-35-5375-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Index	Cureline Specimen label	Clinical Site #	Case #	[REDACTED]	[REDACTED]	Clinical	[REDACTED]
1	[REDACTED]			[REDACTED]		[REDACTED]	[REDACTED]
						[REDACTED]	[REDACTED]
						[REDACTED]	[REDACTED]

[page 2 of 4]
Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit
Lung, left upper lobe	Primary	Tumor	Tissue	OCT	block	1	n/a	n/a
Blood	n/a	Normal	Blood	frozen	tube	1	n/a	n/a

[page 3 of 4]
Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)
surgery	Squamous, non-keratinizing carcinoma	3	2	2	0	none	n/a
blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a

[page 4 of 4]
Tumor cell
%

72

n/a

Source: NCI Genomic Data Commons file 84e02c44-7b61-4980-bb5e-926de2f80c2b (TCGA-35-5375.A93477C8-5EBE-436B-978A-61B573F65471.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).